Surgical pathology report (de-identified scan), TCGA case TCGA-A4-7584, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma), tissue source site International Genomics Consortium, specimen TCGA-A4-7584-01A (Primary Tumor).

[page 1 of 7]
FINAL SURGICAL PATHOLOGY REPORT

Diagnosis:

A. LEFT KIDNEY MASS, PARTIAL NEPHRECTOMY:

- Papillary renal cell carcinoma, Fuhrman nuclear grade 2.
- Multifocal, largest focus 2.5 cm.
- Surgical margin POSITIVE at parenchymal cauterized margin.

PATHOLOGIC TUMOR STAGING SYNOPSIS (KIDNEY):

Type and grade: Papillary renal cell carcinoma, type I, Fuhrman nuclear grade 2.

Primary tumor: pT1a.

Regional lymph nodes: pNX

Distant metastasis: pMX.

Pathologic stage: I.

Lymphovascular invasion: Not identified.

Margin status: R1, cauterized parenchymal margin POSITIVE.

B. , E., F.) PROSTATE, NEW LEFT LATERAL MARGIN, NEW RIGHT LATERAL MARGIN, RADICAL PROSTATECTOMY AND RE-EXCISION OF RIGHT AND LEFT LATERAL MARGINS:

- Prostatic adenocarcinoma, Gleason score 3 + 4 = 7.
- Largest tumor focus 1.7 cm (multifocal).
- Involves right and left prostate lobes.
- Extraprostatic extension identified.
- Perineural invasion identified.
- Surgical margin POSITIVE at left bladder neck margin.

PATHOLOGIC TUMOR STAGING SYNOPSIS (Prostate):

Type and grade: Prostatic adenocarcinoma, Gleason score 3 + 4 = 7.

Primary tumor: pT3a.

Regional lymph nodes: pN0 (0/8, negative for metastatic carcinoma).

Distant metastasis: pMX.

Pathologic stage: III.

Lymphovascular invasion: Not identified.

[page 2 of 7]
FINAL SURGICAL PATHOLOGY REPORT

PROSTATE TUMOR STAGING INFORMATION:

(data derived from current specimen, staging in accordance with or modified from AJCC Cancer Staging Handbook, 7th Ed, and CAP protocol,

Procedure:

Radical prostatectomy.

Specimen type:

Prostate.

Prostate size/weight:

, 3.7 x 3.5 x 3.4 cm.

Tumor Features:

Tumor site:

Right and left prostate lobes.

Tumor size:

Largest focus is 1.7 cm, multifocal.

Tumor quantification:

15% of prostate involved.

Histologic type:

Prostatic adenocarcinoma.

Histologic grade (Gleason pattern):

Primary pattern:

3.

Secondary pattern:

4.

Tertiary pattern:

N/A.

Total Gleason score:

7.

Lymphovascular invasion:

Not identified.

Perineural invasion:

Present.

Extraprostatic extension:

Present.

Seminal vesicle invasion:

Not identified.

Treatment effect:

N/A.

Lymph Nodes:

Negative (0/8).

Margin Evaluation:

Distance to closest margin:

Surgical margin positive at left bladder neck.

Other margins:

N/A.

Pathologic tumor staging descriptors:

Primary tumor (pT):

pT3a.

Regional lymph nodes (pN):

pN0 (0/8).

Distant metastasis (pM):

pMX.

Margin status (R):

R1, positive at left bladder neck.

Additional findings:

High-grade prostatic intraepithelial neoplasia.

Comment:

On the original radical prostatectomy specimen (part B), the right lateral margin is positive, however, the additional tissue submitted as right lateral margin (part F) shows no tumor, therefore the final margin of the right lateral margin is negative.

[page 3 of 7]
FINAL SURGICAL PATHOLOGY REPORT

Source of Specimen:

- A. Left Kidney Mass
- B. Prostatectomy
- C. Right Iliac Obturator
- D. Left Iliac Obturator
- E. Left Lateral Margin
- F. Right Lateral Margin

Clinical History/Operative Dx:

Left kidney mass, prostate cancer

Gross Description:

A. The specimen is labeled left kidney mass and is received without fixative. It consists of a cortical portion of kidney which overall measures 3.3 x 3.1 x 2.9 cm and [REDACTED]. The cortical surface of the kidney appears smooth with intact renal capsule. The surgical margin is inked. The specimen is serially sectioned to reveal a well circumscribed mass measuring 2.5 x 2.5 x 1.8 cm. This mass is variably composed of pale tan to granular reddish and hemorrhagic tissue. It abuts the cortical surface but there is no overlying perirenal fat. It is grossly 0.5 cm from the closest cortical resection margin. Representative sections of this neoplasm are obtained for research purposes. Also in the specimen container is a 4 cm aggregate of lobulated fatty tissue which is serially sectioned and contains no obvious tumor. Representative sections are submitted. Section summary: A1-A4) renal neoplasm and cortical resection margin, A5) peripheral section of neoplasm and representative separate fatty tissue [REDACTED]

B. The specimen is labeled prostate and is received in formalin. It consists of a prostatectomy specimen which [REDACTED]. The prostate gland measures 3.7 x 3.5 x 3.4 cm and includes a partially disrupted 2.5 x 1.5 x 0.7 cm right seminal vesicle, a 1.7 cm segment of right vas deferens, a 1.7 cm segment of left vas deferens, and a short but intact appearing 1.8 x 1.3 x 0.9 cm left seminal vesicle. The right anterior surface of the prostate is inked blue, the left anterior surface is inked green, and the posterior surface is inked black. The prostatic apex, bladder neck, and seminal vesicle / vasa are trimmed. The prostate is divided into right and left halves and is sectioned from apex to bladder neck. The right apical portion of the prostate anteriorly displays pale yellow-tan discoloration in two discrete foci, each 0.7 cm in maximum dimensions. One of these areas is just adjacent to the apical portion of the prostate and the other is located in the mid gland. The prostatic gland parenchyma throughout the left prostate is spongy tan and fibrous. Representative sections are submitted. Section summary: B1) right prostatic apex, B2) left prostatic apex, B3) right bladder neck, B4) left bladder neck, B5) surgical margin right vas deferens, right seminal vesicle, B6) surgical margin left vas deferens, left seminal vesicle, B7-B24) prostate, apex-bladder neck [REDACTED]

C. The specimen is labeled right iliac obturator and is received in formalin. It consists of a 5.5 x 3 x 1.8 cm ovoid portion of fibrofatty tissue and a small 1.1 cm fragment of similar tissue. On dissection there is an ovoid partially fatty replaced 4.5 cm node. In the remaining tissue there is a 2.3 cm node, 1.2 cm

[page 4 of 7]
FINAL SURGICAL PATHOLOGY REPORT

fragment of nodal tissue, and three additional fragmented portions of nodal tissue varying from 0.8 - 1 cm in maximum dimension. On sectioning the largest node has a firm pale tan glistening appearance throughout. The smaller node and nodal fragments have a similar appearance. Representative sections of the largest node are submitted in cassettes C1-C2. The second largest node is bivalved and submitted in cassette C3. A single node is serially sectioned and submitted in cassette C4. Representative sections of the remaining nodal fragments are submitted in cassette C5. [REDACTED]

D. The specimen is labeled left iliac obturator and is received in formalin. It consists of a 7.2 x 2.8 x 1.5 cm ovoid portion of fibrofatty tissue. On dissection there is a large matted portion of nodal tissue measuring 6.5 x 2.7 x 1.5 cm. In the small amount of adherent fatty tissue are three 0.5 - 0.7 cm additional nodes. The largest matted set of nodes is serially sectioned and is composed of pale tan glistening uniform appearing tissue with a peripheral small amount of fatty tissue. Representative sections of the largest matted node are submitted in cassettes D1-D4. The smaller nodes are submitted in cassette D5. [REDACTED]

E. The specimen is labeled left lateral margin and is received in formalin. It consists of a 0.7 x 0.4 x 0.2 cm fragment of tan to reddish brown tissue with a metallic clip along one edge. The specimen is submitted in cassette E1. [REDACTED]

F. The specimen is labeled right lateral margin and is received in formalin. It consists of two metallic clips with a small amount of intervening red-brown soft tissue. The clips are removed and the intervening tissue is submitted in cassette F1. [REDACTED]

Microscopic Description:

A. Microscopic sections have been examined. The microscopic findings are reflected in the diagnosis rendered.

B. Microscopic sections have been examined. The microscopic findings are reflected in the diagnosis rendered.

C. Microscopic sections have been examined. The microscopic findings are reflected in the diagnosis rendered. Immunohistochemistry was performed and interpreted at [REDACTED] for BCL-2, BCL-6, CD10, CD3, CD20, CD23, CD5, CD21, cyclin D1, IHD, and Ki-67. Immunohistochemistry was performed at ProPath and interpreted at [REDACTED] for ZAP 70. Sections show lymph node with effaced architecture with a pseudofollicular pattern of regularly distributed pale areas (proliferation centers) and a dark background of smaller cells. The tumor cells are positive for CD20, CD5, CD23, IgD, and Bcl-2 and negative for CD10, Bcl-6, cyclin D1 and CD3. CD3 stains background T cells. CD21 highlights rare follicular dendritic networks. Ki-67 shows increased staining in the proliferation center areas. The tumor cells are positive for ZAP70. No metastatic carcinoma is identified. No large cell transformation is identified.

D. Microscopic sections have been examined. The microscopic findings are reflected in the diagnosis rendered. Sections show an atypical small lymphoid proliferation histologically similar to that seen in part C.

[REDACTED]

[page 5 of 7]
FINAL SURGICAL PATHOLOGY REPORT

E. Microscopic sections have been examined. The microscopic findings are reflected in the diagnosis rendered.

F. Microscopic sections have been examined. The microscopic findings are reflected in the diagnosis rendered.

[page 6 of 7]
FINAL SURGICAL PATHOLOGY REPORT

Perineural invasion: Present.

Margin status: R1, surgical margin POSITIVE at left bladder neck.

C. - D). LYMPH NODES, ILIAC OBTURATOR, RIGHT AND LEFT, REGIONAL LYMPH NODE BIOPSIES:

- Small lymphocytic lymphoma/chronic lymphocytic leukemia, see comment.
- Eight lymph nodes, negative for metastatic carcinoma (0/8).

COMMENT (specimens C & D): Sections show an atypical small lymphoid proliferation that is positive by immunohistochemistry for CD5, CD20 and CD23 and negative for CD3, cyclin D1, and CD10, consistent with small lymphocytic lymphoma/chronic lymphocytic leukemia. No large cell transformation is identified. The tumor cells are positive for ZAP-70 by immunohistochemistry. An intradepartmental consultation with [REDACTED] was obtained. Results discussed with [REDACTED] hours.

Kidney Tumor Staging Information

(data derived from current specimen, staging in accordance with or modified from AJCC Cancer Staging Handbook, 7th Ed, and CAP protocol [REDACTED])

Procedure:
Specimen type:
Specimen laterality:

Partial nephrectomy.
Partial nephrectomy.
Left.

Tumor Features:

Tumor size:
Tumor focality:
Histologic type:
Histologic grade (Fuhrman nuclear grade):
Sarcomatoid features:
Macroscopic extent of tumor:
Microscopic tumor extension:

2.5 cm.
Multifocal.
Papillary renal cell carcinoma, type I.
Fuhrman nuclear grade 2.
Not identified.
Limited to kidney.
Tumor limited to kidney.

Lymph Nodes:

N/A.

Margin Evaluation:

Distance to closest margin:
Other margins:

Cauterized parenchymal margin POSITIVE.
Peri-renal capsule margin negative.

[page 7 of 7]
FINAL SURGICAL PATHOLOGY REPORT

Pathologic tumor staging descriptors:

Primary tumor (pT):

Regional Lymph nodes (pN):

Distant metastasis (pM):

Margin status (R):

Pathologic stage:

pT1a.

pNX.

pMX.

R1, cauterized parenchymal margin POSITIVE.

I.

Pathologic findings in non-neoplastic kidney:

Focal glomerulosclerosis, chronic inflammatory cell infiltrate histologically similar to that seen in patient's lymph node (small B-cell lymphoma).

Additional pathologic findings:

N/A.

Source: NCI Genomic Data Commons file 4bb52b11-c3a1-4250-bd4a-735f1933d422 (TCGA-A4-7584.D8173141-6C53-4151-8670-586207C0493F.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).